Somatic mutation profile of tumor specimen TCGA-CG-4466-01A (aliquot TCGA-CG-4466-01A-01D-1158-08) from TCGA case TCGA-CG-4466, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 81.4 years (29,739 days).
Specimen TCGA-CG-4466-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36a7e59a-9708-4d12-a677-988f3fb94692.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4466-10A (Blood Derived Normal), aliquot TCGA-CG-4466-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9109335-72c3-4ef0-b352-01b5fb5a72e7

The open-access MAF lists 214 somatic variants for this specimen: 155 protein-altering or splice-affecting, 50 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 50, Nonsense Mutation 8, Frame Shift Del 7, Intron 5, Splice Site 3, Frame Shift Ins 3, RNA 3, 5'UTR 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 69/109 reads (63%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACAN | c.5356A>C p.S1786R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV61369443; called by muse, mutect2, varscan2
- ACTA2 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.405); catalogued as rs886047453, COSV56518168; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS5 | c.1596G>C p.K532N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV53185393; called by muse, mutect2, varscan2
- ADGRB1 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as rs371544443, COSV60103429; called by muse, mutect2, varscan2
- ANKRD30A | c.2533T>G p.F845V (on ENST00000611781; = p.F789V on NM_052997.2) | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV64607178, COSV64621367; called by muse, mutect2, varscan2
- ARHGAP39 | c.254C>G p.A85G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52775802; called by muse, varscan2
- ARID5B | c.3187G>A p.G1063R | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs376805718, COSV54429808, COSV99689130; called by muse, mutect2, varscan2
- ASB15 | c.518C>A p.P173H | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as COSV51929245; called by muse, mutect2, varscan2
- ATF7IP2 | c.1338G>T p.K446N | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV61095424; called by muse, mutect2, varscan2
- ATP10A | c.3443A>T p.N1148I | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV63524442; called by muse, mutect2, varscan2
- ATP2B1 | c.1340T>C p.V447A | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53812867; called by muse, mutect2, varscan2
- B3GALT1 | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.415); catalogued as COSV59909839; called by muse, mutect2, varscan2
- B3GLCT | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.41); catalogued as rs375667011; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNC2 | c.1606C>T p.R536* | Nonsense Mutation (SNP) | VAF 55/81 reads (68%) | catalogued as COSV66157290; called by muse, mutect2, varscan2
- C6orf118 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57819167; called by muse, mutect2, varscan2
- CACNA1D | c.2906C>T p.S969L (on ENST00000350061 / NM_001128840.3; = p.S989L on NM_000720.4) | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55464861; called by muse, mutect2, varscan2
- CACNA1I | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768309039, COSV60803686; called by muse, mutect2, varscan2
- CAPN2 | c.588_589del p.G198Cfs*4 | Frame Shift Del (DEL) | VAF 45/183 reads (25%) | catalogued as rs747013394; called by mutect2, pindel, varscan2
- CDH18 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56961204; called by muse, mutect2, varscan2
- CFH | c.86A>C p.N29T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.392); catalogued as COSV62778838; called by muse, mutect2, varscan2
- CFHR4 | c.1458C>G p.C486W (on ENST00000367416 / NM_001201551.2; = p.C240W on NM_006684.5) | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52235617; called by muse, mutect2, varscan2
- COL16A1 | c.3026A>G p.N1009S | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV54713776; called by muse, mutect2, varscan2
- COL5A1 | c.2384A>G p.K795R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65674693; called by muse, varscan2
- COLGALT2 | c.1655C>A p.A552E | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV62300663; called by muse, mutect2, varscan2
- COPS2 | c.752T>G p.F251C | Missense Mutation (SNP) | VAF 99/117 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV54647593; called by muse, mutect2, varscan2
- CORO6 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV61472043; called by muse, mutect2, varscan2
- CPED1 | c.2668A>C p.T890P | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60013155; called by muse, mutect2, varscan2
- CRAT | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs149016840; called by muse, mutect2
- CSMD3 | c.10352G>T p.R3451I (on ENST00000297405 / NM_001363185.1; = p.R3282I on NM_052900.3) | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52319548; called by muse, varscan2
- CTNND2 | c.1226A>G p.E409G | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV58928437; called by muse, mutect2
- DACH2 | c.778A>T p.S260C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs1243413018, COSV64185854; called by muse, mutect2, varscan2
- DAO | c.1010A>C p.K337T | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV57324564; called by muse, mutect2, varscan2
- DCLK1 | c.431A>G p.K144R | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV55195853, COSV99709434; called by muse, mutect2, varscan2
- DLC1 | c.911A>C p.N304T | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.478); catalogued as COSV52327963, COSV99364612; called by muse, mutect2, varscan2
- DSP | c.7804T>G p.L2602V | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745377828, COSV65796026; called by muse, mutect2, varscan2
- EDNRB | c.1144T>C p.F382L (on ENST00000377211 / NM_001201397.1; = p.F292L on NM_000115.5) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as CM021581, COSV57527910; called by muse, mutect2, varscan2
- EDNRB | c.539G>A p.C180Y (on ENST00000377211 / NM_001201397.1; = p.C90Y on NM_000115.5) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57527936; called by muse, mutect2, varscan2
- EFCAB6 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs139182657; called by muse, mutect2, varscan2
- EIF3A | c.2361G>C p.R787S | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV64963421; called by muse, mutect2, varscan2
- ERBB2 | c.2921C>T p.S974F | Missense Mutation (SNP) | VAF 126/4618 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV54082978; called by muse, mutect2
- ESPL1 | c.5810C>T p.P1937L | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV54477058; called by muse, mutect2, varscan2
- FASTKD3 | c.1315C>A p.H439N | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV52946829; called by muse, mutect2, varscan2
- FAT3 | c.7514T>C p.V2505A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV53116176, COSV53151630; called by muse, mutect2, varscan2
- FAT4 | c.7945C>T p.P2649S | Missense Mutation (SNP) | VAF 59/70 reads (84%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV58708669; called by muse, mutect2, varscan2
- FCRL3 | c.188A>C p.K63T | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.044); catalogued as COSV63844963; called by muse, mutect2, varscan2
- FGF2 | c.826C>A p.Q276K | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV52652946; called by mutect2, varscan2
- FHOD3 | c.4080T>A p.D1360E (on ENST00000359247 / NM_001281739.3; = p.D1377E on NM_025135.5) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57188709; called by muse, mutect2, varscan2
- FLG | c.7403C>G p.S2468* | Nonsense Mutation (SNP) | VAF 162/935 reads (17%) | catalogued as COSV64249260; called by muse, mutect2, varscan2
- FMO3 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV63008627; called by muse, mutect2, varscan2
- GBE1 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV70102900; called by muse, mutect2, varscan2
- GMEB2 | c.1540C>T p.H514Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as COSV56609684; called by muse, mutect2, varscan2
- GNAT1 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as rs1372709296, COSV51697608; called by muse, mutect2
- GPR50 | c.841T>G p.F281V | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV54442850; called by muse, mutect2, varscan2
- GREM2 | c.146T>A p.I49N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV58957263; called by muse, varscan2
- GUCY1A1 | c.2043T>G p.N681K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56650103, COSV56656519; called by muse, mutect2, varscan2
- HCRTR2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as COSV63799129; called by muse, mutect2, varscan2
- IP6K1 | c.997A>G p.S333G | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57696657; called by muse, mutect2, varscan2
- KCNH7 | c.2504A>C p.K835T | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV59813789, COSV59816804; called by muse, mutect2, varscan2
- KCNK15 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.793); catalogued as COSV100865180, COSV65719203; called by muse, mutect2
- KLRG1 | c.558+8T>G | Splice Region (SNP) | VAF 19/124 reads (15%) | catalogued as rs1457266741, COSV56944578; called by muse, mutect2, varscan2
- KRT28 | c.1184A>G p.D395G | Missense Mutation (SNP) | VAF 3206/3420 reads (94%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as rs780797057, COSV60686497, COSV60686688; called by muse, mutect2, varscan2
- LIN7A | c.132A>C p.E44D | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV54017493, COSV99691577, COSV99691982; called by muse, mutect2, varscan2
- LRRC40 | c.1351G>T p.V451F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV63943419; called by muse, mutect2, varscan2
- LTBP1 | c.4048T>C p.Y1350H (on ENST00000404816 / NM_206943.4; = p.Y1024H on NM_000627.4) | Missense Mutation (SNP) | VAF 81/165 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55385406; called by muse, mutect2, varscan2
- MAGEA11 | c.1055T>C p.F352S | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV60758907; called by muse, mutect2
- MAP1A | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs761176236, COSV55808876; called by muse, mutect2, varscan2
- MARF1 | c.3482G>A p.G1161E | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60029262; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 17/87 reads (20%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCTP1 | c.1363A>C p.S455R | Missense Mutation (SNP) | VAF 159/195 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV56533397; called by muse, mutect2, varscan2
- METTL18 | c.250A>C p.S84R | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53682711; called by muse, mutect2, varscan2
- MGAT5 | c.1946G>T p.C649F | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56101235; called by muse, mutect2, varscan2
- MIEF1 | c.701G>C p.R234P | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57480692; called by muse, mutect2, varscan2
- MROH2B | c.587A>C p.K196T | Missense Mutation (SNP) | VAF 146/641 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); catalogued as rs1036570558, COSV68181125, COSV68181709; called by muse, mutect2, varscan2
- MSH4 | c.2768A>T p.D923V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs761860673, COSV54212118; called by muse, mutect2, varscan2
- MUC16 | c.2592A>C p.E864D | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV67494142; called by muse, mutect2, varscan2
- MXRA5 | c.3767A>C p.K1256T | Missense Mutation (SNP) | VAF 147/179 reads (82%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV54250713; called by muse, mutect2, varscan2
- MYH9 | c.2441G>A p.R814Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs760924443, COSV53393158; called by muse, mutect2, varscan2
- MYO10 | c.4664A>G p.N1555S | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV57029945; called by muse, mutect2, varscan2
- NEBL | c.2188A>C p.S730R | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.822); catalogued as COSV65802624; called by muse, mutect2, varscan2
- NECAB1 | c.976A>C p.S326R | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.39); catalogued as COSV70244266; called by muse, mutect2, varscan2
- NELL1 | c.895-2A>G p.X299_splice | Splice Site (SNP) | VAF 43/98 reads (44%) | catalogued as COSV54237186, COSV54240159, COSV54325653; called by muse, mutect2, varscan2
- NGF | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs778266438, COSV65687098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP43 | c.1086T>A p.C362* | Nonsense Mutation (SNP) | VAF 20/113 reads (18%) | catalogued as COSV61191390; called by muse, mutect2, varscan2
- OR2D3 | c.233T>G p.F78C | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58574013; called by muse, mutect2
- OR51A4 | c.476T>G p.L159R | Missense Mutation (SNP) | VAF 72/465 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66750081; called by muse, mutect2, varscan2
- OR52A5 | c.427T>G p.L143V | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV56613991, COSV56614404; called by muse, mutect2, varscan2
- OR5I1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs1260343125, COSV100041338, COSV56886847; called by muse, mutect2, varscan2
- OR6X1 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60010471; called by muse, mutect2, varscan2
- OXCT1 | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as CM005412, COSV52177227; called by muse, mutect2, varscan2
- PARP3 | c.1149G>A p.W383* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV51756607; called by muse, mutect2, varscan2
- PARP6 | c.395+2T>C p.X132_splice | Splice Site (SNP) | VAF 30/126 reads (24%) | catalogued as COSV53005141; called by muse, mutect2, varscan2
- PBXIP1 | c.38T>G p.L13R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV63776543; called by muse, mutect2, varscan2
- PCDH10 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as rs1312444319, COSV52103898; called by muse, mutect2, varscan2
- PCDH15 | c.3663A>C p.Q1221H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100217646, COSV57371515, COSV57394432; called by muse, mutect2, varscan2
- PCLO | c.4591A>C p.T1531P | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as COSV61665994; called by muse, mutect2, varscan2
- PHC1 | c.45T>G p.S15R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV101418712; called by muse, mutect2, varscan2
- PIK3C3 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1031312269, COSV56284675; called by muse, mutect2, varscan2
- PLA2R1 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs139879340; called by muse, mutect2, varscan2
- PNN | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.08); catalogued as rs144685853; called by muse, mutect2, varscan2
- PPIP5K2 | c.93C>G p.D31E | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58609876; called by muse, mutect2, varscan2
- PPP1R13B | c.663C>A p.F221L | Missense Mutation (SNP) | VAF 99/247 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.613); catalogued as COSV52456380; called by muse, mutect2, varscan2
- PTPRB | c.5920G>C p.E1974Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs750940787, COSV54248838, COSV54253544; called by muse, mutect2, varscan2
- PTPRC | c.1076T>G p.L359R | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV61420536; called by muse, mutect2, varscan2
- RBM19 | c.529G>C p.G177R | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV55698506; called by muse, mutect2, varscan2
- RBM24 | c.655G>A p.A219T (on ENST00000379052 / NM_001143942.2; = p.A174T on NM_153020.2) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.281); catalogued as rs761374400, COSV59002569; called by muse, mutect2
- RFPL4B | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV71437790; called by muse, mutect2, varscan2
- RIMBP2 | c.3037T>G p.F1013V | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55466023, COSV55470989, COSV55480263; called by muse, mutect2, varscan2
- RIMS2 | c.4482A>C p.K1494N (on ENST00000666250 / NM_001348490.2; = p.K1065N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51723929; called by muse, mutect2, varscan2
- RNF103 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52897057; called by muse, mutect2, varscan2
- ROBO2 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1405895921, COSV59908258; called by muse, mutect2, varscan2
- RP1 | c.3992A>T p.E1331V | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV55126821; called by muse, mutect2, varscan2
- RXFP3 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752173438, COSV57508245; called by muse, mutect2, varscan2
- SEM1 | c.198G>T p.*66Yext*14 | Nonstop Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV101303931; called by muse, mutect2, varscan2
- SEMA3A | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54881971, COSV54888048; called by muse, mutect2, varscan2
- SEMA5A | c.2117A>C p.K706T | Missense Mutation (SNP) | VAF 43/327 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV66805578; called by muse, mutect2, varscan2
- SERPINA3 | c.1088T>G p.L363R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67587177; called by muse, mutect2, varscan2
- SERPINA7 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV59664815; called by muse, mutect2, varscan2
- SFRP2 | c.590A>C p.K197T | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56838568; called by muse, mutect2, varscan2
- SLC12A5 | c.1043G>A p.R348H (on ENST00000454036 / NM_001134771.2; = p.R325H on NM_020708.5) | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs751583991, COSV54801965; called by muse, mutect2, varscan2
- SLC4A11 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66264019; called by muse, mutect2, varscan2
- SLCO1B3 | c.1402A>C p.S468R | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV53946519; called by muse, mutect2, varscan2
- SLITRK6 | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.285); catalogued as rs1337442872, COSV68391709; called by muse, mutect2, varscan2
- SPTA1 | c.2754G>T p.K918N | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63759411; called by muse, mutect2, varscan2
- SPTAN1 | c.3872C>T p.S1291F | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV63989825; called by muse, mutect2
- SPTBN5 | c.7519C>T p.R2507C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs757228435, COSV58028004; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.23A>C p.K8T | Missense Mutation (SNP) | VAF 35/152 reads (23%) | PolyPhen benign (0.227); catalogued as COSV60349954; called by muse, mutect2, varscan2
- STXBP5L | c.2851A>C p.I951L | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV56535082; called by muse, mutect2, varscan2
- SURF6 | c.674_675insT p.K225Nfs*34 | Frame Shift Ins (INS) | VAF 24/173 reads (14%) | catalogued as COSV100921133; called by pindel, varscan2
- SYCP1 | c.2699T>G p.L900R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65700945; called by muse, mutect2, varscan2
- SYNE1 | c.5115A>C p.E1705D (on ENST00000367255 / NM_182961.4; = p.E1712D on NM_033071.3) | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV55101516; called by muse, mutect2, varscan2
- TAF2 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs773376250, COSV65421136; called by muse, mutect2, varscan2
- TARBP1 | c.4585T>C p.Y1529H | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50206399; called by muse, mutect2, varscan2
- TLR4 | c.1510T>C p.S504P (on ENST00000355622 / NM_138554.5; = p.S464P on NM_003266.4) | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62924225; called by muse, mutect2, varscan2
- TPO | c.2044C>T p.Q682* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as rs1239225665, COSV61111331; called by muse, mutect2, varscan2
- TRIM51 | c.1136T>G p.L379R | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1385927326, COSV99793183; called by muse, mutect2, varscan2
- TRIP11 | c.3053C>T p.T1018M | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as rs147257207; called by muse, mutect2, varscan2
- TRPS1 | c.851G>A p.R284H (on ENST00000220888 / NM_001330599.2; = p.R297H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.549); catalogued as rs376460318, COSV55254044; called by muse, mutect2, varscan2
- TTN | c.44305T>C p.F14769L (on ENST00000591111; = p.F7345L on NM_003319.4) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | PolyPhen benign (0.066); catalogued as COSV60348160; called by muse, mutect2, varscan2
- ULBP1 | c.455A>G p.D152G | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57665093; called by muse, mutect2, varscan2
- USH2A | c.2350T>G p.F784V | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs910033661, COSV56403323, COSV56407014; called by muse, mutect2, varscan2
- USP21 | c.1114+1G>C p.X372_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV57091257; called by muse, mutect2, varscan2
- ZBED4 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV53468155; called by muse, mutect2, varscan2
- ZNF208 | c.1715A>C p.K572T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68107459; called by muse, mutect2, varscan2
- ZNF273 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 45/329 reads (14%) | catalogued as COSV60400820; called by muse, mutect2, varscan2
- ZNF713 | c.958C>G p.L320V (on ENST00000633730 / NM_001366796.2; = p.L333V on NM_182633.3) | Missense Mutation (SNP) | VAF 31/314 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.824); catalogued as COSV70057227; called by muse, mutect2, varscan2
- ZRANB2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs764184838, COSV54674399; called by muse, mutect2, varscan2
- ZZZ3 | c.1291G>C p.G431R | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV66235533; called by muse, mutect2, varscan2
- ACSL5 | c.804del p.G270Efs*3 (on ENST00000354273; = p.G326Efs*3 on NM_016234.3) | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | called by mutect2, pindel, varscan2
- EXT1 | c.302_305dup p.C103Vfs*87 | Frame Shift Ins (INS) | VAF 18/138 reads (13%) | called by mutect2, pindel, varscan2
- FSIP2 | c.20129_20133del p.K6710Ifs*6 | Frame Shift Del (DEL) | VAF 46/102 reads (45%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- UBE2NL | c.60del p.P21Lfs*53 | Frame Shift Del (DEL) | VAF 87/137 reads (64%) | called by mutect2, pindel, varscan2
- YY1AP1 | c.196_200del p.L66Gfs*5 | Frame Shift Del (DEL) | VAF 22/114 reads (19%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.499dup p.C167Lfs*14 | Frame Shift Ins (INS) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- ACTA1 | c.762C>T p.N254= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV64203467, COSV64204264; called by muse, mutect2, varscan2
- ALAD | c.897C>G p.A299= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV52957974; called by muse, mutect2, varscan2
- CD1E | c.192T>C p.T64= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV100936969, COSV63772919; called by muse, mutect2, varscan2
- CD69 | c.249T>G p.S83= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as rs1224028236, COSV57303819; called by muse, mutect2, varscan2
- CDAN1 | c.3045C>T p.R1015= | Silent (SNP) | VAF 24/28 reads (86%) | catalogued as rs758732191, COSV62331067; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH12 | c.1320C>T p.T440= | Silent (SNP) | VAF 52/386 reads (13%) | catalogued as COSV66448220; called by muse, mutect2, varscan2
- CENPF | c.6456T>G p.L2152= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as rs559968112, COSV65279020; called by muse, mutect2, varscan2
- CLEC2D | c.471C>T p.I157= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV51993003; called by muse, mutect2, varscan2
- CSMD3 | c.10287T>C p.S3429= (on ENST00000297405 / NM_001363185.1; = p.S3260= on NM_052900.3) | Silent (SNP) | VAF 29/178 reads (16%) | catalogued as COSV52160457, COSV52319569; called by muse, varscan2
- DNAH17 | c.8601G>A p.Q2867= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV101103532; called by muse, mutect2, varscan2
- ERBB4 | c.3306T>C p.F1102= | Silent (SNP) | VAF 61/78 reads (78%) | catalogued as COSV61522969; called by muse, mutect2, varscan2
- ESR2 | c.1572C>T p.S524= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV50838119; called by muse, mutect2, varscan2
- ETNPPL | c.519T>G p.T173= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as COSV56597564, COSV99625754; called by muse, mutect2, varscan2
- FZD8 | c.1470C>T p.V490= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs1363918500, COSV65968499; called by muse, mutect2, varscan2
- GPR52 | c.789C>T p.Y263= | Silent (SNP) | VAF 82/256 reads (32%) | catalogued as rs756971614, COSV52297944; called by muse, mutect2, varscan2
- GRXCR2 | c.546C>T p.P182= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV65061921; called by muse, mutect2, varscan2
- HBE1 | c.426G>C p.L142= | Silent (SNP) | VAF 54/141 reads (38%) | catalogued as COSV53081391; called by muse, mutect2, varscan2
- HK2 | c.16C>T p.L6= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV51875730; called by muse, mutect2, varscan2
- KCNS3 | c.561C>T p.I187= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs1221716261, COSV58408871; called by muse, mutect2, varscan2
- LEPR | c.2727T>C p.G909= | Silent (SNP) | VAF 69/332 reads (21%) | catalogued as COSV62751926; called by muse, mutect2, varscan2
- LRP1B | c.11052T>C p.S3684= | Silent (SNP) | VAF 68/134 reads (51%) | catalogued as COSV67274912; called by muse, mutect2, varscan2
- MAP3K19 | c.1383C>T p.S461= | Silent (SNP) | VAF 65/239 reads (27%) | catalogued as COSV59642242; called by muse, mutect2, varscan2
- NACC2 | c.813C>T p.D271= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs1020088312; called by muse, mutect2, varscan2
- NLRP2 | c.1548C>A p.T516= | Silent (SNP) | VAF 85/105 reads (81%) | catalogued as COSV54760404; called by muse, mutect2, varscan2
- NR1D2 | c.222T>C p.C74= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as rs1470371875, COSV56993868; called by muse, mutect2, varscan2
- NSD3 | c.3564C>A p.I1188= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV57671621, COSV57674179; called by muse, mutect2, varscan2
- NUP155 | c.258A>G p.R86= (on ENST00000231498 / NM_153485.3; = p.R27= on NM_004298.4) | Silent (SNP) | VAF 24/235 reads (10%) | catalogued as COSV51534777; called by muse, mutect2
- OLFM4 | c.1296C>T p.N432= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as rs201233926, COSV54580540; called by muse, mutect2, varscan2
- OR11H1 | c.837T>A p.T279= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV99421729; called by mutect2, varscan2
- OR13C4 | c.462C>A p.I154= | Silent (SNP) | VAF 40/226 reads (18%) | catalogued as rs757065585, COSV52928490; called by muse, mutect2, varscan2
- OR52E4 | c.441T>G p.A147= | Silent (SNP) | VAF 71/149 reads (48%) | catalogued as COSV57626307; called by muse, mutect2, varscan2
- OR6C3 | c.333T>C p.I111= | Silent (SNP) | VAF 128/294 reads (44%) | catalogued as rs1054641375, COSV65572112; called by muse, mutect2, varscan2
- PLXNC1 | c.750C>G p.P250= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99313895; called by muse, varscan2
- POU2F3 | c.972G>A p.V324= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs765069732, COSV52797783; called by muse, mutect2, varscan2
- PRKACG | c.558C>T p.F186= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs761159477, COSV55257260; called by muse, mutect2, varscan2
- RAPGEF1 | c.2274G>A p.T758= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as rs376156893; called by muse, mutect2, varscan2
- RTL9 | c.1095A>G p.P365= | Silent (SNP) | VAF 128/370 reads (35%) | catalogued as COSV71825620, COSV71826414; called by muse, mutect2, varscan2
- RYR1 | c.14145C>T p.N4715= | Silent (SNP) | VAF 55/97 reads (57%) | catalogued as COSV62110688; called by muse, mutect2, varscan2
- SALL4 | c.996C>T p.S332= | Silent (SNP) | VAF 100/150 reads (67%) | catalogued as rs137963401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A16 | c.726A>C p.V242= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV56266265; called by muse, mutect2, varscan2
- SLC25A38 | c.381C>T p.V127= | Silent (SNP) | VAF 93/304 reads (31%) | catalogued as COSV56195522; called by muse, mutect2, varscan2
- SRRM3 | c.339G>A p.V113= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV58391179; called by muse, mutect2, varscan2
- TBX10 | c.1005G>A p.P335= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1364244463, COSV100039730, COSV56876628; called by muse, mutect2, varscan2
- TRPA1 | c.948T>A p.A316= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV51574161; called by muse, mutect2, varscan2
- UBXN11 | c.738C>T p.D246= (on ENST00000374221 / NM_183008.2; = p.D213= on NM_145345.2) | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs754759642, COSV54625786, COSV54627068; called by muse, mutect2, varscan2
- UNC5C | c.2103C>A p.V701= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV71662280; called by muse, mutect2, varscan2
- VWC2L | c.396T>C p.S132= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as rs746624300, COSV56979125; called by muse, mutect2, varscan2
- WWOX | c.906C>G p.L302= | Silent (SNP) | VAF 76/175 reads (43%) | catalogued as rs377404672, COSV68369715; called by muse, mutect2, varscan2
- ZNF536 | c.459G>A p.T153= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs1490475380, COSV100834827, COSV62833311; called by muse, mutect2, varscan2
- ZNF791 | c.420C>G p.A140= | Silent (SNP) | VAF 88/153 reads (58%) | catalogued as COSV58482809; called by muse, mutect2, varscan2
- DPH6 | c.312+16035C>A | Intron (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99853974; called by muse, mutect2, varscan2
- FOLH1B | n.879T>A | RNA (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- GFOD1 | c.253+16534T>G | Intron (SNP) | VAF 40/76 reads (53%) | catalogued as COSV64953188; called by muse, mutect2, varscan2
- MIR521-1 | n.56C>T | RNA (SNP) | VAF 30/116 reads (26%) | catalogued as rs1456431845; called by muse, mutect2, varscan2
- MIR890 | n.4A>C | RNA (SNP) | VAF 50/74 reads (68%) | called by muse, mutect2, varscan2
- PTHLH | c.-22-198_-22-196del | Intron (DEL) | VAF 77/85 reads (91%) | called by mutect2, pindel, varscan2
- RBPMS | c.528+4930G>C | Intron (SNP) | VAF 60/146 reads (41%) | catalogued as COSV99824560; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-15184T>G | Intron (SNP) | VAF 45/127 reads (35%) | catalogued as COSV67450157; called by muse, mutect2, varscan2
- XIRP2 | c.-99A>C | 5'UTR (SNP) | VAF 42/110 reads (38%) | catalogued as COSV54682928, COSV54690067; called by muse, mutect2, varscan2
